Somatic mutation profile of tumor specimen ALCH-AEPV-TTP1-A (aliquot ALCH-AEPV-TTP1-A-2-0-D-A673-36) from ALCHEMIST case ALCH-AEPV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.6 years (22,484 days).
Specimen ALCH-AEPV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 427b50fb-ced9-4490-a512-192e42980e2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEPV-NB1-A (Blood Derived Normal), aliquot ALCH-AEPV-NB1-A-1-0-D-A673-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f72e6d1-a09e-4d55-9e45-2552a2be1286

The open-access MAF lists 602 somatic variants for this specimen: 411 protein-altering or splice-affecting, 115 silent, 76 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 357, Silent 115, Intron 39, Nonsense Mutation 23, RNA 15, Frame Shift Del 12, 3'UTR 12, Splice Site 11, 5'Flank 5, Splice Region 4, 5'UTR 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.4882C>T p.R1628* | Nonsense Mutation (SNP) | VAF 25/304 reads (8%) | catalogued as rs576472142, COSV67131873; called by muse, mutect2
- ADAMTS5 | c.2667G>C p.R889S | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.998); catalogued as COSV53185542; called by muse, mutect2
- ADSL | c.1138A>C p.M380L | Missense Mutation (SNP) | VAF 46/496 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV99341983; called by muse, mutect2
- AFF2 | c.481C>A p.R161S | Missense Mutation (SNP) | VAF 52/370 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs782411248; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASB7 | c.616A>T p.T206S | Missense Mutation (SNP) | VAF 28/299 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as COSV58403792; called by muse, mutect2
- ATXN2 | c.1769del p.S590Cfs*58 (on ENST00000550104; = p.S430Cfs*58 on NM_002973.4) | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | catalogued as COSV66484680; called by mutect2, pindel, varscan2
- BBS2 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 74/557 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs765030032, COSV99802840; called by muse, mutect2, varscan2
- BPIFB2 | c.707C>A p.P236H | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV50063050, COSV50070490; called by muse, mutect2, varscan2
- BRCA2 | c.986G>C p.R329T | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs1555281666; ClinVar: uncertain significance; called by muse, mutect2
- C9 | c.1351G>T p.D451Y | Missense Mutation (SNP) | VAF 76/435 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV54681540; called by muse, mutect2, varscan2
- C9 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 74/466 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs200646202; called by muse, mutect2, varscan2
- CACNA1E | c.5795G>T p.R1932L | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as COSV100703105; called by muse, mutect2
- CASP14 | c.608T>C p.L203S | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as rs1314192175; called by muse, mutect2
- CC2D2A | c.2006C>A p.A669E | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.764); catalogued as rs953243101; called by muse, mutect2
- CCDC85A | c.1632G>T p.L544F | Missense Mutation (SNP) | VAF 56/405 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs757803396; called by muse, varscan2
- CD177 | c.253C>A p.R85S | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as rs759856388, COSV100945979; called by muse, mutect2
- CDH11 | c.2000G>T p.G667V | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99219413; called by muse, mutect2
- CFAP47 | c.2763G>T p.Q921H | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as COSV52892823; called by muse, mutect2
- CHRM3 | c.128C>G p.S43C | Missense Mutation (SNP) | VAF 36/349 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV55080229, COSV55103433, COSV55104375; called by muse, mutect2
- CILP | c.3377G>C p.R1126P | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV56024942; called by muse, mutect2, varscan2
- CLEC3A | c.502C>G p.P168A (on ENST00000651443; = p.P159A on NM_005752.6) | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1221539973; called by muse, mutect2
- CNTNAP5 | c.3060G>T p.K1020N | Missense Mutation (SNP) | VAF 61/602 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as COSV101443079, COSV101444001; called by muse, mutect2
- COL6A2 | c.829G>T p.G277* | Nonsense Mutation (SNP) | VAF 20/380 reads (5%) | catalogued as COSV55998772; called by muse, mutect2
- CSMD3 | c.10694C>A p.A3565D (on ENST00000297405 / NM_001363185.1; = p.A3396D on NM_052900.3) | Missense Mutation (SNP) | VAF 58/427 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs1301822307, COSV52099455; called by muse, mutect2, varscan2
- CSMD3 | c.3357C>G p.D1119E (on ENST00000297405 / NM_001363185.1; = p.D1015E on NM_052900.3) | Missense Mutation (SNP) | VAF 48/413 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV52264223; called by muse, mutect2, varscan2
- CUBN | c.9191G>C p.C3064S | Missense Mutation (SNP) | VAF 86/696 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV64723093; called by muse, mutect2, varscan2
- CYP20A1 | c.235G>T p.V79F | Missense Mutation (SNP) | VAF 23/261 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs201628887; called by muse, mutect2
- EGFLAM | c.510C>A p.S170R | Missense Mutation (SNP) | VAF 35/255 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.929); catalogued as rs571639364, COSV59305186; called by muse, mutect2, varscan2
- ERCC4 | c.34A>G p.M12V | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); catalogued as rs750358005; called by muse, mutect2, varscan2
- F11 | c.1328G>C p.R443P | Missense Mutation (SNP) | VAF 50/480 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs373212439; called by muse, mutect2
- FAM124B | c.454G>C p.A152P | Missense Mutation (SNP) | VAF 26/297 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99706244; called by muse, mutect2
- FBXO40 | c.1437C>G p.C479W | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767246396; called by muse, mutect2, varscan2
- FCAR | c.689G>T p.R230L | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs373544789; called by muse, mutect2, varscan2
- FCRL5 | c.1843G>C p.G615R | Missense Mutation (SNP) | VAF 20/231 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV62516564; called by muse, mutect2
- FCRL5 | c.1258G>T p.A420S | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.083); catalogued as rs751603300; called by muse, mutect2
- FKBP3 | c.67A>G p.K23E | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV53531377; called by muse, mutect2
- GP2 | c.107C>A p.P36H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV100221547, COSV56895610; called by muse, mutect2, varscan2
- HMCN2 | c.2132G>A p.G711E | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1220565492; called by muse, mutect2, varscan2
- HOXC5 | c.652del p.S218Afs*125 | Frame Shift Del (DEL) | VAF 26/196 reads (13%) | catalogued as rs1471758389; called by mutect2, pindel
- HTR3C | c.1117G>T p.G373C | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1560082437; called by muse, mutect2, varscan2
- IGFBP1 | c.380del p.T127Rfs*3 | Frame Shift Del (DEL) | VAF 11/101 reads (11%) | catalogued as COSV51874689; called by mutect2, pindel, varscan2
- KCNG4 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs551706107; called by muse, mutect2, varscan2
- KCNU1 | c.1630del p.R544Gfs*5 | Frame Shift Del (DEL) | VAF 23/176 reads (13%) | catalogued as COSV101298924; called by mutect2, pindel, varscan2
- KCTD8 | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV100760337; called by muse, mutect2
- LINS1 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs767013535; called by muse, mutect2, varscan2
- LSAMP | c.869G>A p.C290Y | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61291295; called by muse, mutect2, varscan2
- MAGEB6 | c.756G>C p.L252F | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774457033; called by muse, mutect2
- MAP2 | c.4691C>G p.S1564C | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99558275; called by muse, mutect2
- ME2 | c.1320G>T p.R440S | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs759348066; called by muse, mutect2, varscan2
- MMRN1 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 16/313 reads (5%) | catalogued as COSV53338655; called by muse, mutect2
- MYB | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 47/430 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.727); catalogued as rs199722406, COSV57198991; called by muse, mutect2, varscan2
- MYH1 | c.3340G>T p.E1114* | Nonsense Mutation (SNP) | VAF 36/406 reads (9%) | catalogued as COSV56845551; called by muse, mutect2
- MYH2 | c.4342C>A p.L1448I | Missense Mutation (SNP) | VAF 20/311 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs762951575, COSV55437877; called by muse, mutect2
- NALCN | c.2488C>A p.H830N | Missense Mutation (SNP) | VAF 15/307 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1475371083; called by muse, mutect2
- NBEA | c.8306A>G p.Y2769C | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1431620732; called by muse, mutect2
- NEB | c.3352G>T p.A1118S | Missense Mutation (SNP) | VAF 41/333 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1225381477, COSV51467748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP14 | c.1511C>G p.S504C | Missense Mutation (SNP) | VAF 51/714 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.541); catalogued as COSV55063572, COSV55068248; called by muse, mutect2
- NLRP4 | c.1400A>G p.K467R | Missense Mutation (SNP) | VAF 17/271 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.471); catalogued as rs1467086715; called by muse, mutect2
- NOS1 | c.2922C>A p.F974L | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.153); catalogued as COSV57612762; called by muse, mutect2, varscan2
- NUP58 | c.711-2A>C p.X237_splice | Splice Site (SNP) | VAF 16/420 reads (4%) | catalogued as COSV67751224; called by muse, mutect2
- OR2A14 | c.62C>A p.A21E | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68718170; called by muse, mutect2
- OR2B2 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 39/259 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV57580843; called by muse, mutect2, varscan2
- OR2T27 | c.139A>T p.I47F | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1226918616; called by muse, mutect2
- OR4K1 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 29/414 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as COSV53461487; called by muse, mutect2
- OR51F1 | c.631G>C p.D211H | Missense Mutation (SNP) | VAF 20/402 reads (5%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.468); catalogued as COSV58580456; called by muse, mutect2
- OR6T1 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.477); catalogued as COSV100189819; called by muse, mutect2
- OTOL1 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 62/497 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV60007487; called by muse, mutect2, varscan2
- PCDH19 | c.2768G>T p.R923L (on ENST00000373034 / NM_001184880.2; = p.R875L on NM_020766.3) | Missense Mutation (SNP) | VAF 96/597 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55258560; called by muse, mutect2, varscan2
- PCDHB3 | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99165940; called by muse, mutect2, varscan2
- PCDHB5 | c.1698C>G p.N566K | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as COSV50658387; called by muse, mutect2, varscan2
- PCDHB9 | c.666G>T p.R222S | Missense Mutation (SNP) | VAF 36/319 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); catalogued as rs371328067; called by muse, mutect2, varscan2
- PCDHGA6 | c.1435C>A p.P479T | Missense Mutation (SNP) | VAF 54/399 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.783); catalogued as rs1024447978, COSV54044374; called by muse, mutect2, varscan2
- PCDHGA9 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 54/367 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.88); catalogued as rs1436868245; called by muse, mutect2, varscan2
- PDE11A | c.1886G>C p.R629P | Missense Mutation (SNP) | VAF 37/640 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53691028, COSV53699752; called by muse, mutect2
- PEPD | c.1034del p.G345Afs*3 | Frame Shift Del (DEL) | VAF 32/148 reads (22%) | catalogued as COSV54887028; called by mutect2, pindel, varscan2
- PIK3CG | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV63246790; called by muse, mutect2
- PKN1 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99661011; called by muse, mutect2
- POT1 | c.-39-1G>C | Splice Site (SNP) | VAF 6/98 reads (6%) | catalogued as COSV62935050; called by muse, mutect2
- PPP2R2B | c.241G>T p.D81Y (on ENST00000394409; = p.D147Y on NM_181674.2) | Missense Mutation (SNP) | VAF 24/319 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60754854; called by muse, mutect2
- PTPRC | c.1118A>G p.Y373C | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs771923388; called by muse, mutect2
- RALYL | c.715C>A p.L239I | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV72817891; called by muse, mutect2, varscan2
- RELT | c.1006del p.A336Qfs*32 | Frame Shift Del (DEL) | VAF 14/113 reads (12%) | catalogued as COSV50361112; called by mutect2, pindel, varscan2
- RFX2 | c.1967G>A p.R656H | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs571540930, COSV57943661; called by muse, mutect2, varscan2
- RHD | c.121C>G p.Q41E | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.309); catalogued as CM972906, COSV100154932; called by muse, mutect2
- RP1L1 | c.5425G>T p.G1809W | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV66756646, COSV66761798; called by muse, mutect2
- RREB1 | c.494G>C p.R165P | Missense Mutation (SNP) | VAF 36/249 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58559759; called by muse, mutect2, varscan2
- RTL1 | c.2057G>A p.W686* | Nonsense Mutation (SNP) | VAF 8/116 reads (7%) | catalogued as COSV66016453, COSV66016459; called by muse, mutect2
- RUBCNL | c.416C>G p.P139R | Missense Mutation (SNP) | VAF 12/311 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.83); catalogued as COSV59790224; called by muse, mutect2
- RYR1 | c.5213C>A p.T1738K | Missense Mutation (SNP) | VAF 39/453 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV62113004; called by muse, mutect2
- RYR2 | c.12583G>C p.D4195H | Missense Mutation (SNP) | VAF 31/271 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63683798, COSV63686383; called by muse, mutect2, varscan2
- SASH1 | c.2774C>T p.P925L | Missense Mutation (SNP) | VAF 25/405 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as rs1303618057, COSV66565573; called by muse, mutect2
- SETBP1 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 37/620 reads (6%) | catalogued as COSV56333282; called by muse, mutect2
- SH2D7 | c.616del p.R206Gfs*41 | Frame Shift Del (DEL) | VAF 16/134 reads (12%) | catalogued as COSV60926286; called by mutect2, pindel, varscan2
- SIGLEC1 | c.1594A>T p.R532* | Nonsense Mutation (SNP) | VAF 20/215 reads (9%) | catalogued as COSV99170726; called by muse, mutect2
- SIRPB1 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 31/385 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.835); catalogued as rs760160511; called by muse, mutect2
- SLC25A48 | c.805G>T p.G269C (on ENST00000650267; = p.G215C on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1469470841; called by muse, mutect2, varscan2
- SNRPB | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.364); catalogued as rs1313693228; called by muse, varscan2
- SOCS4 | c.715A>T p.T239S | Missense Mutation (SNP) | VAF 16/273 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV59460824; called by muse, mutect2
- SORCS3 | c.494G>C p.R165P | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.503); catalogued as COSV63803147; called by muse, mutect2, varscan2
- SOX17 | c.1240G>T p.V414L | Missense Mutation (SNP) | VAF 43/340 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV52027384; called by muse, mutect2, varscan2
- SUCLG1 | c.319-1G>T p.X107_splice | Splice Site (SNP) | VAF 56/515 reads (11%) | catalogued as CS110418; called by muse, mutect2, varscan2
- SYT14 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 36/550 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746106239, COSV55059396; called by muse, mutect2
- TAF1 | c.3611G>C p.R1204P (on ENST00000373790 / NM_138923.4; = p.R1225P on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as COSV52123409; called by muse, varscan2
- TMEM176B | c.561G>T p.W187C | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58439766; called by muse, mutect2, varscan2
- TMPRSS15 | c.450C>G p.S150R | Missense Mutation (SNP) | VAF 38/452 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.789); catalogued as rs571938840; called by muse, mutect2
- TNN | c.1985G>T p.R662M | Missense Mutation (SNP) | VAF 45/435 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV53423337; called by muse, mutect2, varscan2
- TRIM51 | c.644G>C p.S215T | Missense Mutation (SNP) | VAF 56/850 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV55266447; called by muse, mutect2
- TRIM58 | c.1034G>T p.R345M | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV63570786; called by muse, mutect2
- TRIM58 | c.1035G>T p.R345S | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs376720375; called by muse, mutect2
- TTC14 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56012537; called by muse, mutect2
- WDR46 | c.1093G>T p.V365L | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.216); catalogued as COSV65842598; called by muse, mutect2, varscan2
- ZBTB25 | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 36/496 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67198634; called by muse, mutect2
- ZDHHC13 | c.1553C>A p.P518H | Missense Mutation (SNP) | VAF 19/316 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67981494, COSV67981501; called by muse, mutect2
- ZNF208 | c.3120G>T p.W1040C | Missense Mutation (SNP) | VAF 37/455 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs374010593; called by muse, mutect2
- ZNF43 | c.496A>G p.I166V | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV99048996; called by muse, mutect2, varscan2
- ZNF599 | c.707G>T p.C236F | Missense Mutation (SNP) | VAF 40/429 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1483974504; called by muse, mutect2
- ZP4 | c.1593G>C p.Q531H | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.188); catalogued as COSV63911584; called by muse, mutect2
- ZP4 | c.1041C>A p.Y347* | Nonsense Mutation (SNP) | VAF 21/194 reads (11%) | catalogued as COSV100850506; called by muse, mutect2, varscan2
- ABCA5 | c.1174G>T p.G392C | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACACB | c.5264A>C p.Q1755P | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); called by muse, varscan2
- ADAMTS20 | c.5390C>T p.A1797V | Missense Mutation (SNP) | VAF 44/405 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- AGO3 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- AHNAK2 | c.7391G>T p.W2464L | Missense Mutation (SNP) | VAF 21/276 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- AKT1S1 | c.37G>T p.V13L (on ENST00000344175 / NM_001098633.4; = p.V33L on NM_032375.5) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ALG8 | c.546+2T>G p.X182_splice | Splice Site (SNP) | VAF 41/400 reads (10%) | called by muse, mutect2, varscan2
- ALMS1 | c.6805G>T p.A2269S | Missense Mutation (SNP) | VAF 95/602 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD26 | c.3927G>C p.M1309I | Missense Mutation (SNP) | VAF 80/617 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- APOB | c.5671C>T p.H1891Y | Missense Mutation (SNP) | VAF 19/331 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); called by muse, mutect2
- ARHGEF7 | c.1949G>C p.W650S (on ENST00000375741 / NM_001113511.2; = p.W472S on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ASXL3 | c.3532A>T p.T1178S | Missense Mutation (SNP) | VAF 36/422 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.039); called by muse, mutect2
- ATP11B | c.1739G>T p.S580I | Missense Mutation (SNP) | VAF 30/412 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATR | c.7892A>T p.N2631I | Missense Mutation (SNP) | VAF 45/530 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.435); called by muse, mutect2
- ATR | c.853A>G p.T285A | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- B4GALNT3 | c.472G>C p.A158P | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BMP15 | c.514T>A p.S172T | Missense Mutation (SNP) | VAF 35/285 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BPI | c.1354C>A p.L452I (on ENST00000262865; = p.L448I on NM_001725.3) | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- BTAF1 | c.3668T>C p.I1223T | Missense Mutation (SNP) | VAF 16/456 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.05); called by muse, mutect2
- BTBD10 | c.1087G>A p.G363S | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2
- C2CD5 | c.2579G>C p.R860P | Missense Mutation (SNP) | VAF 56/343 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- C2CD5 | c.2170-2A>T p.X724_splice | Splice Site (SNP) | VAF 52/321 reads (16%) | called by muse, mutect2, varscan2
- C6orf201 | c.199A>T p.I67F | Missense Mutation (SNP) | VAF 61/418 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C8A | c.1626G>T p.W542C | Missense Mutation (SNP) | VAF 27/316 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CA13 | c.430G>C p.V144L | Missense Mutation (SNP) | VAF 35/321 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- CACNA1C | c.5677C>A p.Q1893K (on ENST00000399634 / NM_001167625.1; = p.Q1822K on NM_000719.7) | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CALML3 | c.275T>A p.V92E | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- CARMIL2 | c.3197A>G p.K1066R | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.158); called by muse, mutect2
- CC2D2B | c.658G>T p.V220F | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.237); called by muse, varscan2
- CCDC126 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 42/564 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC57 | c.2147T>G p.L716R | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CCL23 | c.47C>G p.A16G | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- CCND1 | c.770C>G p.S257* | Nonsense Mutation (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2, varscan2
- CD177 | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2
- CD33 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- CD81 | c.561+4C>A | Splice Region (SNP) | VAF 30/268 reads (11%) | called by muse, varscan2
- CDH22 | c.1405G>T p.V469L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH22 | c.100G>T p.G34W | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CDH9 | c.1084G>T p.G362* | Nonsense Mutation (SNP) | VAF 70/507 reads (14%) | called by muse, mutect2, varscan2
- CDNF | c.47T>A p.L16H | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- CEP162 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 38/328 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- CFAP47 | c.8159A>C p.Q2720P | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.793); called by muse, mutect2
- CFAP54 | c.5518G>C p.A1840P | Missense Mutation (SNP) | VAF 60/405 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CHAC2 | c.135G>C p.K45N | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- CHD3 | c.5850C>A p.Y1950* (on ENST00000330494 / NM_001005273.3; = p.Y1916* on NM_005852.4) | Nonsense Mutation (SNP) | VAF 14/260 reads (5%) | called by muse, mutect2
- CLCN1 | c.1144C>A p.L382I | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.942); called by muse, mutect2
- CLEC18C | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNBD1 | c.481C>A p.Q161K | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNN3 | c.149T>G p.L50R | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.142); called by muse, mutect2
- COL2A1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 20/378 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.184); called by muse, mutect2
- COL4A1 | c.2954A>T p.Q985L | Missense Mutation (SNP) | VAF 12/295 reads (4%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.467); called by muse, mutect2
- COLGALT2 | c.395G>C p.G132A | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- COP1 | c.1627A>T p.T543S | Missense Mutation (SNP) | VAF 34/339 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CPNE2 | c.317A>G p.D106G | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CSH2 | c.524A>G p.N175S | Missense Mutation (SNP) | VAF 70/479 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CSMD2 | c.7168G>C p.E2390Q | Missense Mutation (SNP) | VAF 23/332 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.12); called by muse, mutect2
- CSMD2 | c.3314C>A p.T1105N | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- CSMD2 | c.1570C>A p.P524T | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CSMD2 | c.442G>T p.G148C | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- CSMD3 | c.10600A>T p.N3534Y (on ENST00000297405 / NM_001363185.1; = p.N3365Y on NM_052900.3) | Missense Mutation (SNP) | VAF 87/538 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- CSTA | c.281A>T p.E94V | Missense Mutation (SNP) | VAF 34/482 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- CYP4F3 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2
- CYYR1 | c.222G>T p.M74I | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- DIDO1 | c.6065G>T p.G2022V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH6 | c.8923C>A p.Q2975K | Missense Mutation (SNP) | VAF 33/333 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DRP2 | c.2525_2526insC p.R843Sfs*4 | Frame Shift Ins (INS) | VAF 30/197 reads (15%) | called by mutect2, pindel, varscan2
- DUSP4 | c.533C>A p.P178H | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DYSF | c.3766G>A p.A1256T | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, varscan2
- ELK4 | c.358G>T p.V120L | Missense Mutation (SNP) | VAF 24/428 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- EPHA6 | c.2858C>A p.A953E | Missense Mutation (SNP) | VAF 28/285 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- EPS8L1 | c.1823_1824del p.R608Pfs*41 (on ENST00000201647 / NM_133180.3; = p.R481Pfs*41 on NM_017729.3) | Frame Shift Del (DEL) | VAF 14/124 reads (11%) | called by pindel, varscan2
- ERCC3 | c.2269G>A p.V757M | Missense Mutation (SNP) | VAF 25/332 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2
- EVX2 | c.843C>A p.H281Q | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.232); called by muse, mutect2
- FAM155A | c.860A>T p.H287L | Missense Mutation (SNP) | VAF 19/222 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.167); called by muse, mutect2
- FAM47C | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- FAM71E2 | c.1967C>A p.P656Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2
- FAT2 | c.2062G>C p.G688R | Missense Mutation (SNP) | VAF 56/401 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FCAR | c.538T>A p.L180M | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2
- FCRLA | c.115G>T p.A39S (on ENST00000367959; = p.A22S on NM_032738.4) | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- FFAR3 | c.818_819insG p.F274Lfs*16 | Frame Shift Ins (INS) | VAF 108/556 reads (19%) | called by mutect2, pindel, varscan2
- FGFR1 | c.539C>T p.S180F (on ENST00000447712 / NM_023110.3; = p.S178F on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- FJX1 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FLG | c.1678G>C p.G560R | Missense Mutation (SNP) | VAF 53/572 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by muse, mutect2
- FMO2 | c.775C>A p.Q259K | Missense Mutation (SNP) | VAF 30/416 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.335); called by muse, mutect2
- FSCN1 | c.613C>A p.R205S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSTL4 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 46/335 reads (14%) | called by muse, mutect2, varscan2
- FZD3 | c.668C>T p.T223I | Missense Mutation (SNP) | VAF 18/261 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GC | c.1346C>G p.A449G | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- GCSAML | c.253A>T p.N85Y | Missense Mutation (SNP) | VAF 46/536 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.407); called by muse, mutect2
- GDF2 | c.100G>C p.G34R | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GNL1 | c.1234T>G p.C412G | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- GOLGA6L9 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 27/941 reads (3%) | called by muse, mutect2
- GPATCH2L | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- GPATCH8 | c.1894G>T p.A632S | Missense Mutation (SNP) | VAF 24/323 reads (7%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.001); called by muse, mutect2
- GPR89B | c.909G>T p.M303I | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- GPRASP1 | c.3328G>A p.E1110K | Missense Mutation (SNP) | VAF 58/398 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- GZF1 | c.1107C>A p.H369Q | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- HEATR4 | c.1935C>A p.N645K | Missense Mutation (SNP) | VAF 17/253 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.053); called by muse, mutect2
- HECTD1 | c.7247C>T p.P2416L | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.259); called by muse, mutect2
- HEMK1 | c.602A>G p.E201G | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2
- HERC4 | c.1146+1G>T p.X382_splice | Splice Site (SNP) | VAF 26/312 reads (8%) | called by muse, mutect2
- HES3 | c.128T>A p.V43E | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HIF1AN | c.688T>C p.Y230H | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- HMCN1 | c.15255A>T p.K5085N | Missense Mutation (SNP) | VAF 32/544 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); called by muse, mutect2
- HYDIN | c.10575G>T p.Q3525H | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.081); called by muse, mutect2
- HYDIN | c.6084_6103del p.L2030Hfs*19 | Frame Shift Del (DEL) | VAF 21/195 reads (11%) | called by mutect2, pindel
- IGHV1-24 | c.138C>A p.Y46* | Nonsense Mutation (SNP) | VAF 34/397 reads (9%) | called by muse, mutect2
- IGHV1-58 | c.236A>G p.Y79C | Missense Mutation (SNP) | VAF 29/422 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.195); called by muse, mutect2
- IGHV3-21 | c.221G>T p.S74I | Missense Mutation (SNP) | VAF 42/501 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.28); called by muse, mutect2
- IMPG2 | c.2536G>A p.G846S | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- ISM2 | c.1118C>G p.T373S (on ENST00000342219 / NM_199296.3; = p.L258V on NM_182509.4) | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.13); called by muse, mutect2
- ITGAD | c.1154T>C p.M385T | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- KCND3 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNH4 | c.2929T>C p.S977P | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH8 | c.1268C>A p.A423D | Missense Mutation (SNP) | VAF 19/330 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); called by muse, mutect2
- KCNT2 | c.1474A>G p.I492V | Missense Mutation (SNP) | VAF 23/372 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.139); called by muse, mutect2
- KIAA0100 | c.119C>A p.A40E | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- KIAA1217 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF15 | c.1940A>T p.Q647L | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.075); called by muse, mutect2
- KIF9 | c.2068C>A p.L690I (on ENST00000265529 / NM_001377474.1; = p.L625I on NM_022342.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- KMT5C | c.616G>T p.D206Y | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KRT84 | c.358C>A p.P120T | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- L3MBTL3 | c.234C>A p.S78R | Missense Mutation (SNP) | VAF 31/228 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- LAMA1 | c.2251T>G p.C751G | Missense Mutation (SNP) | VAF 13/414 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- LARP4B | c.682A>G p.K228E | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, varscan2
- LILRA2 | c.263C>A p.T88N | Missense Mutation (SNP) | VAF 28/413 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.086); called by muse, mutect2
- LMX1A | c.923G>C p.S308T | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.11); called by muse, mutect2
- LRP1 | c.4462G>T p.G1488W | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP2 | c.5867T>A p.L1956Q | Missense Mutation (SNP) | VAF 63/397 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- LRP2 | c.167A>T p.D56V | Missense Mutation (SNP) | VAF 46/688 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2
- LRRC15 | c.1123A>T p.N375Y | Missense Mutation (SNP) | VAF 29/294 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRRC37A3 | c.127G>C p.V43L | Missense Mutation (SNP) | VAF 18/544 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.341); called by muse, mutect2
- LRRK1 | c.3341G>A p.G1114E | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- LRRK2 | c.290A>C p.Q97P | Missense Mutation (SNP) | VAF 28/502 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- LRWD1 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 33/272 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- LYST | c.10619G>C p.G3540A | Missense Mutation (SNP) | VAF 40/558 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAP7D1 | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.056); called by muse, mutect2
- MASP1 | c.238-1G>A p.X80_splice | Splice Site (SNP) | VAF 36/279 reads (13%) | called by muse, mutect2, varscan2
- MBD5 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 48/701 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- MCM2 | c.1166G>C p.R389P | Missense Mutation (SNP) | VAF 16/185 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.087); called by muse, mutect2
- MEOX2 | c.335C>A p.P112H | Missense Mutation (SNP) | VAF 16/211 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.2); called by muse, mutect2
- MKS1 | c.400T>G p.Y134D | Missense Mutation (SNP) | VAF 109/685 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- MMP27 | c.398A>T p.E133V | Missense Mutation (SNP) | VAF 31/312 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2
- MORN5 | c.394A>T p.T132S | Missense Mutation (SNP) | VAF 53/428 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MPPED2 | c.793A>C p.T265P | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- MRGPRX4 | c.403C>G p.P135A | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MROH2A | c.2701A>G p.I901V | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MRPS9 | c.542C>G p.A181G | Missense Mutation (SNP) | VAF 18/393 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.141); called by muse, mutect2
- MTPAP | c.156A>T p.T52= | Splice Region (SNP) | VAF 29/255 reads (11%) | called by muse, mutect2, varscan2
- MYCBP2 | c.3887G>T p.W1296L (on ENST00000357337; = p.W1334L on NM_015057.5) | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MYH2 | c.5719C>A p.H1907N | Missense Mutation (SNP) | VAF 28/526 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYO3A | c.1604G>T p.G535V | Missense Mutation (SNP) | VAF 56/542 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO3B | c.3869G>C p.R1290T | Missense Mutation (SNP) | VAF 18/424 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MYO5A | c.3802A>G p.I1268V | Missense Mutation (SNP) | VAF 53/494 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MYT1L | c.1727C>A p.A576E | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NBEA | c.6946C>A p.Q2316K | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NDST4 | c.2059G>T p.A687S | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2
- NEMF | c.1273G>T p.D425Y | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- NLGN2 | c.220T>A p.Y74N | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRX1 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.088); called by muse, mutect2
- NPAP1 | c.2368C>A p.H790N | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- NPAS4 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 57/215 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- NPR1 | c.1240G>T p.D414Y | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2
- NPR1 | c.1605G>C p.G535= | Splice Region (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- NPY5R | c.657G>T p.Q219H | Missense Mutation (SNP) | VAF 29/276 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NR0B1 | c.988G>T p.G330C | Missense Mutation (SNP) | VAF 20/283 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2
- NRROS | c.626A>T p.H209L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- NT5C3B | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 47/381 reads (12%) | called by muse, mutect2, varscan2
- NUDT17 | c.212_213del p.F71Cfs*13 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, pindel
- NXPE4 | c.34T>A p.L12M | Missense Mutation (SNP) | VAF 33/373 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.07); called by muse, mutect2
- OBSCN | c.7970C>A p.S2657Y | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- OGDHL | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- OR2Y1 | c.379T>C p.C127R | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4A5 | c.624C>G p.F208L | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.651); called by muse, mutect2
- OR56A3 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 28/410 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- OR5M10 | c.401C>A p.S134Y | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.498); called by muse, mutect2
- OR5P2 | c.693C>G p.H231Q | Missense Mutation (SNP) | VAF 25/362 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.05); called by muse, mutect2
- OR6C2 | c.288_289delinsT p.S97Vfs*38 | Frame Shift Del (DEL) | VAF 38/319 reads (12%) | called by pindel, varscan2*
- OR6M1 | c.721C>A p.H241N | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR8K5 | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); called by muse, mutect2
- PAPPA2 | c.4183A>T p.S1395C | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.682); called by muse, mutect2
- PAQR9 | c.429C>A p.S143R | Missense Mutation (SNP) | VAF 23/241 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PARP15 | c.1063+2T>C p.X355_splice (on ENST00000464300 / NM_001113523.3; = p.X121_splice on NM_152615.2) | Splice Site (SNP) | VAF 20/331 reads (6%) | called by muse, mutect2
- PCARE | c.2445G>T p.K815N | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCDHB8 | c.659C>A p.S220Y | Missense Mutation (SNP) | VAF 47/786 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- PCDHGA6 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCNT | c.1874G>T p.C625F | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- PDCD11 | c.3379G>A p.D1127N | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- PDGFRA | c.2039G>T p.G680V | Missense Mutation (SNP) | VAF 26/544 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PEAK1 | c.3766A>T p.S1256C | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- PEG10 | c.955G>T p.G319* (on ENST00000482108 / NM_001040152.2; = p.G352V on NM_015068.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/155 reads (8%) | called by muse, mutect2
- PHACTR3 | c.850del p.V284Sfs*83 | Frame Shift Del (DEL) | VAF 34/188 reads (18%) | called by mutect2, pindel, varscan2
- PHF21B | c.859C>A p.L287M | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PHOX2B | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PKNOX1 | c.856T>A p.Y286N | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PKP4 | c.179A>C p.Q60P | Missense Mutation (SNP) | VAF 43/284 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PLCD3 | c.1661A>T p.Q554L | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PLEKHG1 | c.876C>A p.D292E | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLEKHG4B | c.3770G>T p.C1257F (on ENST00000283426; = p.C1613F on NM_052909.5) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); called by muse, mutect2
- PLPPR4 | c.1785C>A p.N595K | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2
- POTEF | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 47/487 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- PPOX | c.222+3G>A | Splice Region (SNP) | VAF 17/266 reads (6%) | called by muse, mutect2
- PPP4R3C | c.1630A>G p.I544V | Missense Mutation (SNP) | VAF 34/480 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.05); called by muse, mutect2
- PRAMEF15 | c.1132C>A p.R378S | Missense Mutation (SNP) | VAF 28/564 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.098); called by muse, mutect2
- PRAMEF4 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); called by muse, mutect2
- PRKDC | c.799G>C p.V267L | Missense Mutation (SNP) | VAF 28/291 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- PROP1 | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2
- PRPF38A | c.341T>A p.I114N | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.105); called by muse, mutect2
- PRPF6 | c.1567C>T p.Q523* | Nonsense Mutation (SNP) | VAF 24/678 reads (4%) | called by muse, mutect2
- PSMC6 | c.208A>T p.I70F (on ENST00000612399; = p.I56F on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2
- PSMD14 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 53/419 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PTPN5 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 23/417 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); called by muse, mutect2
- PTPRU | c.1241G>A p.C414Y | Missense Mutation (SNP) | VAF 24/255 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RAB11FIP5 | c.1817T>A p.I606N | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- REG3G | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 14/301 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RELN | c.8265G>T p.M2755I | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.573); called by muse, mutect2
- RGS9 | c.1063A>T p.K355* | Nonsense Mutation (SNP) | VAF 48/384 reads (13%) | called by muse, mutect2, varscan2
- ROBO3 | c.3696G>T p.W1232C | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.078); called by muse, mutect2
- RSF1 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 26/321 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.054); called by muse, mutect2
- RUBCN | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 41/384 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RYR2 | c.7732G>T p.G2578* | Nonsense Mutation (SNP) | VAF 24/217 reads (11%) | called by muse, mutect2, varscan2
- S100A12 | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 13/209 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.676); called by muse, mutect2
- SCN8A | c.3965G>T p.G1322V | Missense Mutation (SNP) | VAF 69/492 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SENP5 | c.1745G>A p.W582* | Nonsense Mutation (SNP) | VAF 14/224 reads (6%) | called by muse, mutect2
- SENP5 | c.1746G>T p.W582C | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SEZ6 | c.2724C>A p.S908R | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- SEZ6L | c.2474T>C p.L825P | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.46); PolyPhen probably damaging (1); called by muse, mutect2
- SFMBT2 | c.1435A>C p.K479Q | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- SGO2 | c.2312C>T p.T771I | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2
- SH3GL3 | c.200A>C p.K67T | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SIGLEC9 | c.635C>A p.T212N | Missense Mutation (SNP) | VAF 13/211 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SLC25A2 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 37/349 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC25A48 | c.70C>A p.H24N | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2
- SLC30A10 | c.976G>C p.V326L | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.259); called by muse, varscan2
- SLC4A10 | c.1321C>T p.P441S (on ENST00000446997 / NM_001354461.2; = p.P411S on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC4A9 | c.1678G>C p.G560R (on ENST00000507527 / NM_001258428.2; = p.G536R on NM_031467.3) | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SLC5A7 | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLFN14 | c.1547G>T p.S516I | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2
- SLIT2 | c.2930G>C p.G977A | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.16); called by muse, mutect2
- SP110 | c.899-1G>T p.X300_splice | Splice Site (SNP) | VAF 37/641 reads (6%) | called by muse, mutect2
- SPATA31D1 | c.2455G>T p.V819L | Missense Mutation (SNP) | VAF 54/517 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPATA9 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- SPATC1 | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 47/421 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- SPTBN4 | c.3998G>T p.R1333L | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SSU72P8 | c.331T>C p.C111R | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SSU72P8 | c.332G>T p.C111F | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- STAU1 | c.1556C>G p.S519C (on ENST00000371856 / NM_001319135.1; = p.S438C on NM_004602.3) | Missense Mutation (SNP) | VAF 14/305 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2
- STON1 | c.986G>T p.R329M | Missense Mutation (SNP) | VAF 40/322 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by mutect2, varscan2
- SUPV3L1 | c.917C>A p.T306N | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SVIL | c.6312C>A p.Y2104* (on ENST00000355867 / NM_021738.3; = p.Y1678* on NM_003174.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/299 reads (8%) | called by muse, mutect2
- SYCP2 | c.2856C>A p.S952R | Missense Mutation (SNP) | VAF 27/422 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2
- SYNE2 | c.16043G>T p.C5348F | Missense Mutation (SNP) | VAF 56/706 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2
- SYNPO2L | c.204T>G p.S68R | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- SYT9 | c.841C>A p.L281M | Missense Mutation (SNP) | VAF 23/408 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TANC1 | c.2875G>T p.A959S | Missense Mutation (SNP) | VAF 46/334 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TANC2 | c.2828A>G p.K943R | Missense Mutation (SNP) | VAF 54/365 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- TAS2R50 | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TBL1X | c.260A>T p.Q87L | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2
- TBX5 | c.943C>A p.Q315K | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2
- TCP11X2 | c.740C>T p.T247I | Missense Mutation (SNP) | VAF 55/642 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.16); called by muse, mutect2
- THBS2 | c.296C>G p.T99R | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THNSL2 | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); called by muse, mutect2
- TMEM209 | c.140+1G>A p.X47_splice | Splice Site (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2
- TMEM63C | c.2108G>A p.G703D | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.067); called by muse, mutect2
- TMPRSS4 | c.676A>C p.K226Q | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.1); called by muse, mutect2
- TOP2B | c.1387G>T p.D463Y (on ENST00000264331 / NM_001330700.2; = p.D458Y on NM_001068.3) | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TPST2 | c.620A>T p.Y207F | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- TRAV12-2 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.105); called by muse, mutect2
- TRIM29 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- TRIM64C | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 32/617 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.374); called by muse, mutect2
- TRNAU1AP | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 17/293 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- TRO | c.1397A>G p.K466R | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- TUBGCP5 | c.475A>T p.M159L | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- UNC80 | c.2597T>C p.L866P | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP31 | c.2912C>A p.A971E | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UTP18 | c.561A>T p.Q187H | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- VCP | c.1223G>T p.G408V | Missense Mutation (SNP) | VAF 26/299 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VSTM2B | c.440G>C p.R147P | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- WDR6 | c.304G>C p.G102R | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.077); called by muse, mutect2
- WDR64 | c.1025-1G>T p.X342_splice | Splice Site (SNP) | VAF 13/180 reads (7%) | called by muse, mutect2
- XPC | c.1590G>T p.Q530H | Missense Mutation (SNP) | VAF 20/572 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2
- ZEB1 | c.1726G>T p.A576S | Missense Mutation (SNP) | VAF 65/534 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZIC1 | c.1039A>C p.S347R | Missense Mutation (SNP) | VAF 27/264 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- ZNF33B | c.2336G>T p.*779Lext*4 | Nonstop Mutation (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- ZNF343 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 48/302 reads (16%) | called by muse, varscan2
- ZNF382 | c.148A>T p.M50L | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF404 | c.1469C>G p.T490S | Missense Mutation (SNP) | VAF 112/353 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZNF423 | c.2533A>T p.T845S (on ENST00000563137 / NM_001379286.1; = p.T837S on NM_015069.4) | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF423 | c.1130G>A p.S377N (on ENST00000563137 / NM_001379286.1; = p.S369N on NM_015069.4) | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- ZNF454 | c.235G>T p.G79* | Nonsense Mutation (SNP) | VAF 17/151 reads (11%) | called by muse, mutect2, varscan2
- ZNF726 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2
- ZNF729 | c.2513C>G p.A838G | Missense Mutation (SNP) | VAF 37/610 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.019); called by muse, mutect2
- ZNF804A | c.466G>T p.V156F | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.466); called by muse, mutect2
- ABCC12 | c.3321G>T p.V1107= | Silent (SNP) | VAF 10/218 reads (5%) | catalogued as COSV100253241; called by muse, mutect2
- ABCD4 | c.1206C>T p.P402= | Silent (SNP) | VAF 15/283 reads (5%) | called by muse, mutect2
- ABO | c.909C>T p.S303= | Silent (SNP) | VAF 19/186 reads (10%) | catalogued as COSV71743452; called by muse, mutect2, varscan2
- ADCY10 | c.378C>A p.I126= | Silent (SNP) | VAF 66/738 reads (9%) | called by muse, mutect2
- ADGRF2 | c.1938G>C p.V646= (on ENST00000296862 / NM_001368115.2; = p.V578= on NM_153839.7) | Silent (SNP) | VAF 40/197 reads (20%) | called by muse, mutect2, varscan2
- AFF2 | c.3873C>T p.T1291= | Silent (SNP) | VAF 21/148 reads (14%) | catalogued as rs781961148; called by muse, mutect2, varscan2
- AGPS | c.1965A>G p.R655= | Silent (SNP) | VAF 76/637 reads (12%) | called by muse, mutect2, varscan2
- AKAP9 | c.11010C>A p.A3670= (on ENST00000359028; = p.A3646= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 63/487 reads (13%) | called by muse, mutect2, varscan2
- ANK2 | c.4287A>G p.S1429= | Silent (SNP) | VAF 50/617 reads (8%) | catalogued as rs72556369; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- ANKRD27 | c.1201C>T p.L401= | Silent (SNP) | VAF 31/222 reads (14%) | catalogued as rs774543855; called by muse, mutect2, varscan2
- AOC3 | c.940C>T p.L314= | Silent (SNP) | VAF 26/168 reads (15%) | called by muse, mutect2, varscan2
- ASTN2 | c.864C>T p.P288= | Silent (SNP) | VAF 12/111 reads (11%) | called by muse, mutect2, varscan2
- ATP2A2 | c.1065A>T p.T355= | Silent (SNP) | VAF 41/298 reads (14%) | called by muse, mutect2, varscan2
- AZIN2 | c.501G>C p.L167= | Silent (SNP) | VAF 14/286 reads (5%) | called by muse, mutect2
- BCAM | c.1479A>T p.A493= | Silent (SNP) | VAF 11/93 reads (12%) | called by muse, varscan2
- BMP15 | c.261C>T p.N87= | Silent (SNP) | VAF 22/135 reads (16%) | called by muse, mutect2, varscan2
- C10orf71 | c.2028G>T p.V676= | Silent (SNP) | VAF 8/210 reads (4%) | catalogued as COSV100110694; called by muse, mutect2
- C9orf57 | c.90T>A p.G30= (on ENST00000377024 / NM_001371610.1; = p.G8= on NM_001128618.2) | Silent (SNP) | VAF 45/410 reads (11%) | called by muse, mutect2, varscan2
- CD84 | c.432T>G p.S144= | Silent (SNP) | VAF 16/184 reads (9%) | called by muse, mutect2
- CLTRN | c.588C>T p.I196= | Silent (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- CMKLR1 | c.690G>T p.L230= (on ENST00000312143 / NM_001142344.2; = p.L228= on NM_004072.3) | Silent (SNP) | VAF 21/157 reads (13%) | called by muse, mutect2, varscan2
- CNNM1 | c.1461G>T p.V487= | Silent (SNP) | VAF 12/207 reads (6%) | called by muse, mutect2
- CNNM3 | c.759G>T p.P253= | Silent (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- CNTN5 | c.849T>A p.P283= | Silent (SNP) | VAF 22/284 reads (8%) | called by muse, mutect2
- COL4A5 | c.220C>A p.R74= | Silent (SNP) | VAF 68/450 reads (15%) | catalogued as COSV60366888; called by muse, mutect2, varscan2
- CP | c.930T>C p.R310= | Silent (SNP) | VAF 50/586 reads (9%) | catalogued as rs773472310; called by muse, mutect2
- CSMD1 | c.6498G>A p.E2166= (on ENST00000520002; = p.E2165= on NM_033225.6) | Silent (SNP) | VAF 19/190 reads (10%) | called by muse, mutect2, varscan2
- CYP20A1 | c.234G>T p.V78= | Silent (SNP) | VAF 26/269 reads (10%) | called by muse, mutect2
- DCAF12L2 | c.288C>G p.T96= | Silent (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- DENND2A | c.1512C>A p.S504= | Silent (SNP) | VAF 16/254 reads (6%) | called by muse, mutect2
- DIS3L | c.39C>T p.T13= | Silent (SNP) | VAF 11/120 reads (9%) | called by muse, mutect2
- DNAH3 | c.10074C>T p.Y3358= | Silent (SNP) | VAF 41/279 reads (15%) | catalogued as rs1441630753; called by muse, mutect2, varscan2
- FAM184B | c.2877C>A p.T959= | Silent (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
- FAM24A | c.66C>A p.A22= | Silent (SNP) | VAF 24/309 reads (8%) | catalogued as rs780133848, COSV64406191; called by muse, mutect2
- FBXO40 | c.1896C>A p.S632= | Silent (SNP) | VAF 14/98 reads (14%) | called by muse, varscan2
- FCRLB | c.579G>T p.L193= | Silent (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2, varscan2
- FER1L5 | c.348C>A p.V116= | Silent (SNP) | VAF 11/158 reads (7%) | called by muse, mutect2
- FLG | c.3117G>A p.Q1039= | Silent (SNP) | VAF 42/476 reads (9%) | catalogued as rs1238258468; called by muse, mutect2
- FOXF1 | c.420G>T p.R140= | Silent (SNP) | VAF 23/159 reads (14%) | called by muse, mutect2, varscan2
- FYB1 | c.342C>A p.G114= | Silent (SNP) | VAF 81/432 reads (19%) | called by muse, mutect2, varscan2
- GALNT15 | c.336G>A p.R112= | Silent (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- GJB3 | c.537C>A p.A179= | Silent (SNP) | VAF 20/254 reads (8%) | called by muse, mutect2
- GNAS | c.471A>T p.P157= | Silent (SNP) | VAF 57/581 reads (10%) | called by muse, mutect2
- GOLT1A | c.240A>T p.L80= | Silent (SNP) | VAF 20/252 reads (8%) | called by muse, mutect2
- GPR158 | c.1314C>G p.V438= | Silent (SNP) | VAF 9/225 reads (4%) | called by muse, mutect2
- GPR161 | c.591C>A p.A197= | Silent (SNP) | VAF 20/236 reads (8%) | called by muse, mutect2
- GRHL1 | c.1797C>A p.T599= | Silent (SNP) | VAF 21/243 reads (9%) | called by muse, mutect2
- GRIN2A | c.616C>T p.L206= | Silent (SNP) | VAF 14/390 reads (4%) | called by muse, mutect2
- GYPA | c.24A>G p.V8= | Silent (SNP) | VAF 12/362 reads (3%) | called by muse, mutect2
- HELZ | c.3330G>T p.R1110= | Silent (SNP) | VAF 72/499 reads (14%) | catalogued as COSV100699084; called by muse, mutect2, varscan2
- HERC6 | c.741C>T p.H247= | Silent (SNP) | VAF 10/192 reads (5%) | called by muse, mutect2
- HPSE | c.1551G>T p.R517= | Silent (SNP) | VAF 12/198 reads (6%) | called by muse, mutect2
- HSPG2 | c.2997G>A p.G999= | Silent (SNP) | VAF 25/387 reads (6%) | called by muse, mutect2
- IFNA14 | c.309C>A p.T103= | Silent (SNP) | VAF 41/407 reads (10%) | called by muse, mutect2, varscan2
- IGFN1 | c.1275C>T p.I425= (on ENST00000295591 / NM_001367841.1; = p.I2882= on NM_001164586.2) | Silent (SNP) | VAF 47/272 reads (17%) | called by muse, mutect2, varscan2
- IRGC | c.618C>A p.G206= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV54982990; called by muse, mutect2, varscan2
- ITGAD | c.2739G>T p.L913= | Silent (SNP) | VAF 18/211 reads (9%) | called by muse, mutect2
- KCNV1 | c.855C>T p.P285= | Silent (SNP) | VAF 30/219 reads (14%) | catalogued as COSV52086495; called by muse, mutect2, varscan2
- KIF7 | c.1029C>A p.A343= | Silent (SNP) | VAF 12/123 reads (10%) | called by mutect2, varscan2
- KRT26 | c.1119T>A p.L373= | Silent (SNP) | VAF 98/422 reads (23%) | called by muse, varscan2
- LILRA2 | c.420C>A p.T140= | Silent (SNP) | VAF 16/255 reads (6%) | called by muse, mutect2
- LILRA2 | c.1170G>T p.V390= | Silent (SNP) | VAF 75/386 reads (19%) | called by muse, varscan2
- LMTK2 | c.2457C>T p.S819= | Silent (SNP) | VAF 35/249 reads (14%) | catalogued as rs995944831; called by muse, mutect2, varscan2
- MMS22L | c.1605T>C p.F535= | Silent (SNP) | VAF 38/200 reads (19%) | catalogued as rs749254110; called by muse, mutect2, varscan2
- MOB2 | c.474C>T p.A158= | Silent (SNP) | VAF 18/232 reads (8%) | called by muse, mutect2
- MUC19 | c.630T>A p.G210= | Silent (SNP) | VAF 12/270 reads (4%) | called by muse, mutect2
- MYBPC2 | c.1554G>T p.S518= | Silent (SNP) | VAF 5/85 reads (6%) | catalogued as COSV63101723; called by muse, mutect2
- MYH6 | c.5679C>T p.T1893= | Silent (SNP) | VAF 19/366 reads (5%) | called by muse, mutect2
- MYO7B | c.3996C>A p.A1332= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- NAPSA | c.1014G>T p.T338= | Silent (SNP) | VAF 28/155 reads (18%) | called by muse, mutect2, varscan2
- NDRG1 | c.33T>A p.A11= | Silent (SNP) | VAF 15/376 reads (4%) | catalogued as COSV60485742; called by muse, mutect2
- NLRP4 | c.2430C>A p.R810= | Silent (SNP) | VAF 12/216 reads (6%) | called by muse, mutect2
- NRXN2 | c.3045G>C p.T1015= | Silent (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- NUP98 | c.5109C>G p.L1703= (on ENST00000359171 / NM_001365126.1; = p.L1686= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 9/196 reads (5%) | catalogued as COSV61429700; called by muse, mutect2
- OR11L1 | c.483G>A p.L161= | Silent (SNP) | VAF 27/250 reads (11%) | catalogued as rs1307762716, COSV100869459; called by muse, mutect2, varscan2
- OR4A15 | c.570C>T p.T190= | Silent (SNP) | VAF 26/301 reads (9%) | catalogued as rs61748701, COSV59037441; called by muse, mutect2
- OR4Q3 | c.189G>T p.L63= | Silent (SNP) | VAF 26/392 reads (7%) | called by muse, mutect2
- OR6F1 | c.843G>C p.V281= | Silent (SNP) | VAF 31/358 reads (9%) | called by muse, mutect2
- P2RX2 | c.1407C>G p.A469= (on ENST00000343948 / NM_170683.4; = p.A371= on NM_012226.5) | Silent (SNP) | VAF 25/123 reads (20%) | called by muse, mutect2, varscan2
- PBX1 | c.744G>T p.L248= | Silent (SNP) | VAF 16/256 reads (6%) | called by muse, mutect2
- PCDH12 | c.369C>A p.I123= | Silent (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- PCDH15 | c.1794C>A p.I598= | Silent (SNP) | VAF 50/590 reads (8%) | catalogued as COSV57303833, COSV57330842; called by muse, mutect2
- PCDHGA2 | c.2077C>T p.L693= | Silent (SNP) | VAF 25/209 reads (12%) | catalogued as rs968751970; called by muse, mutect2, varscan2
- PCDHGB4 | c.1584C>T p.L528= | Silent (SNP) | VAF 24/225 reads (11%) | catalogued as rs772524229; called by muse, mutect2, varscan2
- PDILT | c.627C>A p.G209= | Silent (SNP) | VAF 26/220 reads (12%) | catalogued as COSV56701856; called by muse, mutect2
- PEG10 | c.954G>T p.A318= (on ENST00000482108 / NM_001040152.2; = p.G352W on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/157 reads (8%) | called by muse, mutect2
- PPP1R12C | c.768G>C p.R256= | Silent (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- PPP1R14A | c.127C>A p.R43= | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as rs1160917260; called by muse, mutect2, varscan2
- PPP1R7 | c.21G>T p.A7= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV99297966; called by muse, mutect2, varscan2
- PPWD1 | c.183C>A p.A61= | Silent (SNP) | VAF 12/122 reads (10%) | called by muse, varscan2
- PTPRO | c.1935T>C p.S645= | Silent (SNP) | VAF 86/524 reads (16%) | called by muse, mutect2, varscan2
- RHOBTB1 | c.1032C>T p.D344= | Silent (SNP) | VAF 23/267 reads (9%) | catalogued as rs1332231684; called by muse, mutect2
- RSPO1 | c.15G>T p.L5= | Silent (SNP) | VAF 31/329 reads (9%) | called by muse, mutect2
- SCART1 | c.2304T>A p.A768= | Silent (SNP) | VAF 19/142 reads (13%) | called by muse, mutect2, varscan2
- SEMA4F | c.894A>T p.P298= | Silent (SNP) | VAF 23/158 reads (15%) | called by muse, mutect2, varscan2
- SLC1A3 | c.729C>T p.A243= | Silent (SNP) | VAF 87/537 reads (16%) | called by muse, mutect2, varscan2
- SLC6A13 | c.1608C>G p.L536= | Silent (SNP) | VAF 23/124 reads (19%) | called by muse, mutect2, varscan2
- SMG5 | c.1233G>T p.P411= | Silent (SNP) | VAF 17/147 reads (12%) | called by muse, mutect2, varscan2
- SMOX | c.906G>T p.G302= | Silent (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- SPATA18 | c.933C>A p.S311= | Silent (SNP) | VAF 9/184 reads (5%) | called by muse, mutect2
- SPATA31A1 | c.1179C>A p.P393= | Silent (SNP) | VAF 30/558 reads (5%) | called by muse, mutect2
- SPATC1 | c.96G>T p.R32= | Silent (SNP) | VAF 49/422 reads (12%) | called by muse, mutect2, varscan2
- SSC5D | c.3975C>T p.P1325= | Silent (SNP) | VAF 14/334 reads (4%) | called by muse, mutect2
- TGM6 | c.1920G>A p.A640= | Silent (SNP) | VAF 24/224 reads (11%) | catalogued as rs768950448; ClinVar: benign; called by muse, mutect2, varscan2
- THADA | c.1770C>T p.S590= | Silent (SNP) | VAF 16/270 reads (6%) | called by muse, mutect2
- TMEM132B | c.1722C>A p.T574= | Silent (SNP) | VAF 30/198 reads (15%) | called by muse, mutect2, varscan2
- TRAJ45 | c.57C>T p.I19= | Silent (SNP) | VAF 20/136 reads (15%) | called by muse, mutect2, varscan2
- TRAV25 | c.153G>A p.Q51= | Silent (SNP) | VAF 26/280 reads (9%) | called by muse, mutect2
- TRIM22 | c.1056G>T p.S352= | Silent (SNP) | VAF 25/365 reads (7%) | catalogued as rs140700337; called by muse, mutect2
- TRPS1 | c.1563G>C p.T521= (on ENST00000220888 / NM_001330599.2; = p.T534= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/423 reads (13%) | catalogued as COSV55236533; called by muse, mutect2, varscan2
- USP6 | c.1308C>A p.A436= | Silent (SNP) | VAF 28/437 reads (6%) | called by muse, mutect2
- VARS1 | c.1857G>A p.G619= | Silent (SNP) | VAF 11/71 reads (15%) | called by muse, mutect2, varscan2
- XIRP2 | c.1122A>G p.T374= (on ENST00000628543; = p.T549= on NM_152381.6) | Silent (SNP) | VAF 44/356 reads (12%) | called by muse, mutect2, varscan2
- ZKSCAN5 | c.363G>A p.A121= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs991659163, COSV58742271; called by muse, mutect2
- ZNF592 | c.2895G>A p.R965= | Silent (SNP) | VAF 34/179 reads (19%) | called by muse, mutect2, varscan2
- AC136604.1 | n.636C>G | RNA (SNP) | VAF 15/194 reads (8%) | called by muse, mutect2
- ACAP2 | c.54-20727T>A | Intron (SNP) | VAF 29/290 reads (10%) | called by muse, mutect2, varscan2
- ADAM10 | c.207-9259C>T | Intron (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
- AGAP12P | n.1421C>G | RNA (SNP) | VAF 62/320 reads (19%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847457 G>T | 5'Flank (SNP) | VAF 26/164 reads (16%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502256 G>A | 5'Flank (SNP) | VAF 46/484 reads (10%) | called by muse, mutect2
- ARGLU1 | c.573+75G>A | Intron (SNP) | VAF 34/726 reads (5%) | called by muse, mutect2
- BMP7 | c.1036-29G>T | Intron (SNP) | VAF 25/321 reads (8%) | called by muse, mutect2
- BTN2A3P | n.1371G>T | RNA (SNP) | VAF 49/310 reads (16%) | called by muse, mutect2, varscan2
- CACNB4 | chr2:152099054 ins G | 5'Flank (INS) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
- CAV3 | c.-39C>T | 5'UTR (SNP) | VAF 10/221 reads (5%) | catalogued as COSV100664281; called by muse, mutect2
- CCDC74B | c.296-203C>T | Intron (SNP) | VAF 22/182 reads (12%) | called by muse, mutect2, varscan2
- CEP104 | c.427-9C>G | Intron (SNP) | VAF 14/143 reads (10%) | called by muse, mutect2, varscan2
- CEP126 | c.507-1712C>T | Intron (SNP) | VAF 36/463 reads (8%) | called by muse, mutect2
- CEP41 | c.*4864G>C | 3'UTR (SNP) | VAF 32/388 reads (8%) | called by muse, mutect2
- CHRNA4 | c.*2290C>A | 3'UTR (SNP) | VAF 144/638 reads (23%) | called by muse, mutect2, varscan2
- DENND2B | c.2172+557C>G | Intron (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- DIP2C | c.85+38396G>C | Intron (SNP) | VAF 10/211 reads (5%) | called by muse, mutect2
- DYNLRB2 | chr16:80540801 C>A | 5'Flank (SNP) | VAF 16/366 reads (4%) | catalogued as rs1223456367; called by muse, mutect2
- EMBP1 | n.1140C>G | RNA (SNP) | VAF 15/315 reads (5%) | called by muse, mutect2
- EPB41L3 | c.1340-47G>T | Intron (SNP) | VAF 16/157 reads (10%) | called by muse, mutect2
- EYS | c.1767-8506C>A | Intron (SNP) | VAF 28/286 reads (10%) | called by muse, mutect2, varscan2
- FAM174A | c.*36A>G | 3'UTR (SNP) | VAF 14/161 reads (9%) | called by muse, mutect2
- FDXR | c.178-18_178-17delinsT | Intron (DEL) | VAF 8/93 reads (9%) | called by pindel, varscan2*
- FMO3 | c.133-1994C>G | Intron (SNP) | VAF 21/171 reads (12%) | called by muse, mutect2, varscan2
- GCNT2P1 | n.654C>T | RNA (SNP) | VAF 54/312 reads (17%) | catalogued as rs1312888244; called by muse, mutect2, varscan2
- GCSAML | c.-56-10412G>A | Intron (SNP) | VAF 14/246 reads (6%) | catalogued as rs1450654218; called by muse, mutect2
- GDA | c.*2371T>C | 3'UTR (SNP) | VAF 44/379 reads (12%) | called by muse, mutect2, varscan2
- HBD | c.*4C>A | 3'UTR (SNP) | VAF 40/610 reads (7%) | catalogued as rs1303308789, COSV99496621; called by muse, mutect2
- HID1 | c.1637-50G>C | Intron (SNP) | VAF 13/115 reads (11%) | catalogued as rs1244680150; called by muse, mutect2, varscan2
- HLA-DPB2 | n.222G>C | RNA (SNP) | VAF 12/174 reads (7%) | catalogued as rs1382408955; called by muse, mutect2
- HSP90AB3P | n.2023C>A | RNA (SNP) | VAF 34/366 reads (9%) | called by muse, mutect2
- IGFBP5 | c.338-19C>A | Intron (SNP) | VAF 16/104 reads (15%) | called by muse, mutect2, varscan2
- KLHL7 | c.121-5837C>T | Intron (SNP) | VAF 43/450 reads (10%) | catalogued as rs747425940, COSV59165456; called by muse, mutect2
- LINC01036 | n.76C>A | RNA (SNP) | VAF 12/243 reads (5%) | catalogued as rs1293660156; called by muse, mutect2
- LINC01036 | n.77C>A | RNA (SNP) | VAF 13/246 reads (5%) | called by muse, mutect2
- LINC02313 | n.169C>T | RNA (SNP) | VAF 20/303 reads (7%) | called by muse, mutect2
- LINC02860 | n.742G>C | RNA (SNP) | VAF 22/220 reads (10%) | catalogued as rs1458679404; called by muse, mutect2, varscan2
- LMF1 | c.*346C>T | 3'UTR (SNP) | VAF 45/371 reads (12%) | called by muse, mutect2, varscan2
- MAP4K1 | c.418-23C>A | Intron (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2, varscan2
- MARK2 | c.289-16G>A | Intron (SNP) | VAF 11/142 reads (8%) | called by muse, mutect2
- MEGF10 | c.1693+1585G>T | Intron (SNP) | VAF 24/356 reads (7%) | called by muse, mutect2
- MGAT4D | c.-1C>A | 5'UTR (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- MYO1C | c.2760+21C>T | Intron (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- NCR2 | c.644+872C>G | Intron (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- NCR2 | c.644+873C>G | Intron (SNP) | VAF 7/131 reads (5%) | called by muse, mutect2
- NEU4 | c.-4+114C>A | Intron (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2
- NPIPB1P | n.118C>A | RNA (SNP) | VAF 44/476 reads (9%) | called by muse, mutect2
- OBSCN | c.18662-2820C>A | Intron (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- P4HA3 | c.*66G>T | 3'UTR (SNP) | VAF 46/395 reads (12%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157324 C>T | 3'Flank (SNP) | VAF 27/614 reads (4%) | catalogued as rs1232224474; called by muse, mutect2
- POLR3C | c.1373+20G>C | Intron (SNP) | VAF 12/221 reads (5%) | called by muse, mutect2
- POU3F4 | c.*27C>A | 3'UTR (SNP) | VAF 34/263 reads (13%) | called by muse, mutect2, varscan2
- PRDM13 | c.144+18C>T | Intron (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
- PSG5 | c.964+11C>G | Intron (SNP) | VAF 26/360 reads (7%) | called by muse, mutect2
- PSG5 | c.431-2991C>A | Intron (SNP) | VAF 52/160 reads (33%) | catalogued as COSV100742681; called by muse, mutect2, varscan2
- PSMF1 | c.*1138C>G | 3'UTR (SNP) | VAF 47/232 reads (20%) | catalogued as COSV55677353; called by muse, mutect2, varscan2
- RBFOX1 | c.318+117T>A | Intron (SNP) | VAF 62/383 reads (16%) | called by muse, mutect2, varscan2
- RBFOX1 | c.28-185061C>A | Intron (SNP) | VAF 37/232 reads (16%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159114 G>A | 5'Flank (SNP) | VAF 12/156 reads (8%) | catalogued as rs111958693; called by muse, mutect2
- SNORD116-17 | chr15:25088211 del A | 3'Flank (DEL) | VAF 10/118 reads (8%) | called by mutect2, pindel
- SOX6 | c.-5+136A>T | Intron (SNP) | VAF 23/435 reads (5%) | called by muse, mutect2
- TAF1 | c.4322-4609G>T | Intron (SNP) | VAF 28/170 reads (16%) | called by muse, mutect2, varscan2
- TBC1D10C | c.468-38C>A | Intron (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- TEPSIN | c.*67A>T | 3'UTR (SNP) | VAF 13/212 reads (6%) | called by muse, mutect2
- TLE4 | c.1341-673G>C | Intron (SNP) | VAF 36/395 reads (9%) | called by muse, mutect2
- TMEM183B | n.1066C>A | RNA (SNP) | VAF 18/162 reads (11%) | called by muse, mutect2, varscan2
- TSPAN10 | c.789-379G>C | Intron (SNP) | VAF 7/162 reads (4%) | called by muse, mutect2
- UGT2B27P | n.1210G>A | RNA (SNP) | VAF 36/481 reads (7%) | catalogued as rs771304492; called by muse, mutect2
- Unknown | chr21:16194528 T>G | IGR (SNP) | VAF 16/193 reads (8%) | called by muse, mutect2
- VAPB | c.*816G>T | 3'UTR (SNP) | VAF 100/387 reads (26%) | called by mutect2, varscan2
- WT1 | c.965+24C>A | Intron (SNP) | VAF 22/428 reads (5%) | called by muse, mutect2
- XIRP2 | c.*544G>A | 3'UTR (SNP) | VAF 57/410 reads (14%) | catalogued as COSV54726811; called by muse, mutect2, varscan2
- ZAP70 | c.838-30C>T | Intron (SNP) | VAF 34/255 reads (13%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+4621C>A | Intron (SNP) | VAF 71/644 reads (11%) | catalogued as rs568032420; called by muse, mutect2, varscan2
- ZNF890P | n.889T>A | RNA (SNP) | VAF 14/130 reads (11%) | called by muse, mutect2, varscan2
